Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8360, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8360-01A (Primary Tumor).

[page 1 of 4]
Case ID	Gross Description	Microscopic Description
[REDACTED]	Segment of the stomach with a plate-like tumor of 8 cm in its largest dimension with the features of necrosis extension to the fatty tissue; the tumor spreads up to the peritoneum and adheres to the lesser omentum; fatty tissue contains dense, hyperemic lymph nodes; omentum demonstrates fibrosis and hyperemia.	Adenocarcinoma of the stomach (intestinal type), G2, invasion into subserosa. Fifteen examined lymph nodes demonstrate follicular hyperplasia. Omentum -- without changes.

[page 2 of 4]
Diagnosis Details	Comments	Formatted Path Report
Tumor Features: Ulcerating, Tumor Extent: Subserosa, Venous Invasion: Absent, Margins: Absent, Treatment Effect:		STOMACH TISSUE CHECKLIST Specimen type: Subtotal gastrectomy Tumor site: Fundus Tumor size: 0 x 0 x 8 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma, intestinal type Histologic grade: Moderately differentiated Tumor extent: Subserosa Lymph nodes: 0/15 positive for metastasis (Greater and lesser omentum 0/15) Lymphatic invasion: Not specified Venous invasion: Absent Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 3 of 4]
	ID	Excision Date

[page 4 of 4]
Laterality

Source: NCI Genomic Data Commons file 5fd204b4-30dd-4849-946a-9fa19996af9b (TCGA-BR-8360.9879214F-A6C8-4D8D-8244-873EB5AE5F8A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).